Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70U, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70U-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal, right (adrenalectomy): Pheochromocytoma, no convincing vascular or capsular penetration identified, see Note.

NOTE: There are multiple small tumor fragments on the surface of the periadrenal fat. This probably represents tumor contaminants related to specimen handling and do not represent extracapsular invasion of the fat. The immunohistochemical staining showed the tumor cells positive for chromogranin and synaptophysin. S-100 highlights sustentacular cells.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the Specialized Diagnostics Unit of the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Pheochromocytoma Specimen
Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: large R-adrenal Post-Operative
Diagnosis: same
Pre-Operative Diagnosis: pheo

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received is one container labeled with the patient's name, medical record number, and further specified as "right adrenal gland". Received fresh is an adrenalectomy specimen (10 x 5.5 x 2.7 cm), weighing 66.3 gm overall (with the surrounding adipose tissue), partially surrounded by adipose tissue. A mass (5.7 x 3 x 2.7 cm) is present. The cut surface of the mass is inked in black, bisected, revealing a light tan, homogeneous cut surface with central necrosis. A total of 4 x 2 x 0.3 cm tissue, not involving the inked margin is procured for under sterile conditions, remaining sent to Pathology. Pictures are taken. At Surgical Pathology, the specimen received matched the above description. Representative sections of the tumor were submitted in white cassettes for permanent processing. Grossly normal adrenal gland was submitted in white cassette for permanent processing.

Gross description dictated by

No consultants

[page 2 of 2]
Surgical Pathology

Final Results

#

#

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file e88ed516-cd83-4eeb-b708-107f11e48889 (TCGA-QR-A70U.0EF224F3-DAFD-4312-828E-CE93AA6FE7DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).